TCGA case TCGA-13-0903 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8783e4b0-2b62-45d5-8cd9-f5a71cc0138e

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 42 years; Vital status: Alive.

Diagnoses (1)
1. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 43.0 years (15,705 days); Year of diagnosis: 2004; Method of diagnosis: Surgical Resection; FIGO stage: Stage IV; Tumor grade: G3; Prior treatment: No; Days to last follow up: 3,887 days (10.6 years).
   Pathology details: Residual tumor measurement: No macroscopic disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 22 days; Days to treatment end: 127 days; Number of cycles: 6; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Cetuximab; Treatment intent type: Adjuvant; Days to treatment start: 22 days; Days to treatment end: 141 days; Treatment dose: 250 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 22 days; Days to treatment end: 127 days; Number of cycles: 6; Treatment dose: 1,050 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Cetuximab; Treatment intent type: Adjuvant; Days to treatment start: 169 days; Days to treatment end: 335 days; Treatment dose: 250 mg/m2.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 1,441 days (3.9 years); Disease response: With Tumor.
- Days to follow up: 3,887 days (10.6 years); Disease response: Tumor Free.
- Karnofsky performance status: 80; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-13-0903-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.8; Shortest dimension: 0.4.
  Slide TCGA-13-0903-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 90; Percent normal cells: 10; Percent necrosis: 15; Percent stromal cells: 0.
  Slide TCGA-13-0903-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 90; Percent normal cells: 10; Percent necrosis: 15; Percent stromal cells: 0.
- Sample TCGA-13-0903-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; History neoadjuvant treatment: No; Performance status timing: Pre-Adjuvant Therapy; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor; Performance status timing: Pre-Adjuvant Therapy.
- Follow-up form 2: Treatment outcome at TCGA followup: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,887 days; disease-specific survival: no event (censored), 3,887 days; progression-free interval: no event (censored), 3,887 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-13-0903-01A-01D-0399-01): tumor purity 0.88, ploidy 1.86, whole-genome doublings 0.
